Somatic mutation profile of tumor specimen TCGA-D1-A16G-01A (aliquot TCGA-D1-A16G-01A-31D-A12J-09) from TCGA case TCGA-D1-A16G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,065 days).
Specimen TCGA-D1-A16G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eb1c0de-ae48-4b23-91b8-e5c232ad7802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16G-10A (Blood Derived Normal), aliquot TCGA-D1-A16G-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30453c49-d146-41d6-b8c6-48b0844210ee

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | catalogued as rs122456135, CM980291, COSV59903610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1177C>T p.R393* (on ENST00000281708 / NM_001349798.2; = p.R313* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 35/162 reads (22%) | hotspot (GDC flag); catalogued as COSV55892695; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 74/216 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 54/106 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ARHGAP35 | c.2804del p.H935Pfs*13 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as COSV68334221; called by mutect2, pindel, varscan2
- ARHGAP35 | c.3571G>T p.E1191* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV68334223; called by muse, mutect2
- C12orf65 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV53516828; called by muse, mutect2, varscan2
- CACNA1B | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201499802, COSV53134106; called by muse, mutect2, varscan2
- CCDC144A | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV60700576; called by muse, mutect2, varscan2
- CDX4 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV100999152, COSV65171389; called by muse, mutect2, varscan2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- DACH2 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64162737; called by muse, mutect2, varscan2
- DMD | c.10215C>A p.N3405K | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58936751; called by muse, varscan2
- EFNA4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); catalogued as rs769941477, COSV63018733; called by muse, mutect2, varscan2
- KDM2A | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs754925482, COSV67083408; called by muse, mutect2, varscan2
- LIG1 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54394598; called by muse, mutect2, varscan2
- LIG1 | c.576A>C p.K192N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV54394606; called by muse, mutect2, varscan2
- LPA | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755587107, COSV60305033; called by muse, mutect2, varscan2
- NAA15 | c.2184del p.D728Efs*7 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as COSV56721691; called by mutect2, pindel, varscan2
- PLXNB1 | c.5401C>T p.R1801C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs759846178, COSV56486536; called by muse, mutect2, varscan2
- SOX5 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58641893; called by muse, mutect2, varscan2
- SRRM4 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57422964; called by muse, mutect2, varscan2
- THADA | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as rs1558958535, COSV57690021; called by muse, mutect2
- TTN | c.26128C>T p.P8710S (on ENST00000591111; = p.P7783S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | PolyPhen benign (0.001); catalogued as COSV60243643; called by muse, mutect2
- WDR70 | c.1562A>G p.Q521R | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV54280100; called by muse, mutect2
- XIRP2 | c.10036G>T p.A3346S (on ENST00000628543; = p.A3521S on NM_152381.6) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs767957119, COSV54722883; called by muse, mutect2, varscan2
- ZDHHC14 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58193168, COSV58195749; called by muse, mutect2, varscan2
- ZNF486 | c.221T>C p.M74T | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV58721329; called by muse, mutect2
- ZNF813 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as rs775475809, COSV67177552; called by muse, mutect2
- ZP4 | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63913044; called by muse, mutect2
- RAD18 | c.1134_1136del p.D378del | In Frame Del (DEL) | VAF 105/537 reads (20%) | called by mutect2, pindel, varscan2
- COL4A5 | c.981T>C p.D327= | Silent (SNP) | VAF 91/396 reads (23%) | catalogued as rs1165228239, COSV100091094, COSV60367878; called by muse, mutect2, varscan2
- DCST2 | c.111C>A p.A37= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV55053702; called by muse, mutect2
- EPHB2 | c.207G>A p.Q69= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV65864991; called by muse, mutect2, varscan2
- FBLN5 | c.273G>A p.P91= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as rs368771780; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- INTS1 | c.6525G>A p.A2175= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs557528129, COSV67178987; called by muse, mutect2, varscan2
- LSP1 | c.24G>A p.P8= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as rs377303273; called by muse, mutect2, varscan2
- NPEPPS | c.2245C>T p.L749= | Silent (SNP) | VAF 125/533 reads (23%) | catalogued as COSV59104452; called by muse, mutect2, varscan2
- PRKAG2 | c.129C>T p.F43= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs770946241, COSV55236966; called by muse, mutect2, varscan2
- SALL4 | c.2466G>T p.R822= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV53854954; called by muse, mutect2, varscan2
